Somatic mutation profile of tumor specimen TCGA-D3-A3ML-06A (aliquot TCGA-D3-A3ML-06A-11D-A21A-08) from TCGA case TCGA-D3-A3ML, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 70.8 years (25,873 days).
Specimen TCGA-D3-A3ML-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35cd4586-574d-4b17-929a-15cbfef113a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A3ML-10A (Blood Derived Normal), aliquot TCGA-D3-A3ML-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78e6a8e5-f9f5-4eed-866e-0fdad4af95ac

The open-access MAF lists 1,141 somatic variants for this specimen: 727 protein-altering or splice-affecting, 380 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 660, Silent 380, Nonsense Mutation 36, RNA 13, Splice Site 12, Intron 12, Splice Region 11, Frame Shift Del 4, Translation Start Site 3, 3'UTR 3, 5'Flank 3, 5'UTR 2.

Variants (750 of 1,141; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 52/136 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57595738; called by muse, mutect2, varscan2
- COL3A1 | c.3041G>A p.G1014E | Missense Mutation (SNP) | VAF 52/81 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912916, CM920209, COSV58581416, COSV58592685; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EZH2 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as rs193921148, CM120183, COSV57456778, COSV57463449; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ5 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 153/161 reads (95%) | catalogued as rs1554201137, COSV59651569; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MN1 | c.3883C>T p.R1295* | Nonsense Mutation (SNP) | VAF 64/137 reads (47%) | catalogued as rs147334255, CM162266, COSV56559880; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 245/388 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- OTC | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72554349, CM971099, COSV99234177; ClinVar: pathogenic; called by muse, varscan2
- RTKN2 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | hotspot (GDC flag); catalogued as rs772033296, COSV65679700, COSV65679972; called by muse, mutect2, varscan2
- SCN5A | c.3994C>T p.P1332S (on ENST00000333535 / NM_198056.3; = p.P1331S on NM_000335.5) | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs794728877, COSV61131070; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 72/156 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen possibly damaging (0.664); catalogued as rs147148566, COSV53202265, COSV53220854; called by muse, mutect2, varscan2
- ABCA12 | c.7246C>T p.P2416S (on ENST00000272895 / NM_173076.3; = p.P2098S on NM_015657.3) | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55952245; called by muse, mutect2, varscan2
- ABCA4 | c.4346G>A p.W1449* | Nonsense Mutation (SNP) | VAF 24/73 reads (33%) | catalogued as rs61750143, CM990053, COSV64675114; ClinVar: not provided; called by muse, mutect2, varscan2
- ABCB11 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 117/185 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.661); catalogued as COSV55595154, COSV55595243; called by muse, mutect2, varscan2
- ABCC9 | c.3269G>A p.G1090E | Missense Mutation (SNP) | VAF 76/171 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53977739; called by muse, mutect2, varscan2
- ABRA | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 221/511 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61732947; called by muse, mutect2, varscan2
- AC004997.1 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated, low confidence (0.07); catalogued as COSV53164956; called by muse, mutect2, varscan2
- AC008397.2 | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 104/191 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV53208262; called by muse, mutect2, varscan2
- AC008397.2 | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53208269; called by muse, mutect2, varscan2
- AC097637.1 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | catalogued as COSV59726894; called by muse, mutect2, varscan2
- AC126283.2 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs756596684, COSV67099257; called by muse, mutect2, varscan2
- ACAN | c.4222G>A p.E1408K | Missense Mutation (SNP) | VAF 160/228 reads (70%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.839); catalogued as rs1394961166, COSV61364181; called by muse, varscan2
- ACSM2B | c.795G>A p.W265* | Nonsense Mutation (SNP) | VAF 85/216 reads (39%) | catalogued as rs765182724, COSV61656914; called by muse, mutect2, varscan2
- ACTL8 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV64861946; called by muse, mutect2, varscan2
- ADAMTS7 | c.3758C>T p.P1253L | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV66308363; called by muse, mutect2, varscan2
- ADAMTS9 | c.5678C>T p.S1893L | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV55785134; called by muse, mutect2, varscan2
- ADCY8 | c.1274A>G p.N425S | Missense Mutation (SNP) | VAF 89/121 reads (74%) | SIFT tolerated (0.83); PolyPhen benign (0.044); catalogued as rs750970943, COSV53915383; called by muse, mutect2, varscan2
- ADGRF5 | c.1991G>A p.G664E | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs755276570, COSV51936653, COSV99346322; called by muse, mutect2, varscan2
- ADGRV1 | c.4895G>A p.G1632E | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67989628; called by muse, mutect2, varscan2
- ADGRV1 | c.9989G>A p.R3330K | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV67984740, COSV67989632; called by muse, mutect2, varscan2
- ADGRV1 | c.16043C>T p.T5348I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV67986796; called by muse, mutect2, varscan2
- ADHFE1 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 127/552 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52557077; called by muse, mutect2, varscan2
- ADORA3 | c.54G>A p.M18I | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53986304; called by muse, mutect2, varscan2
- AFDN | c.2692C>T p.L898F | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.757); catalogued as COSV60049046; called by muse, mutect2, varscan2
- AFF3 | c.1339G>T p.G447C | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT tolerated (0.28); PolyPhen benign (0.105); catalogued as COSV57860975; called by muse, mutect2, varscan2
- AFP | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 29/77 reads (38%) | catalogued as rs764510228, COSV99890079; called by muse, mutect2, varscan2
- AGR2 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV68597007; called by muse, mutect2, varscan2
- AHNAK | c.9367C>T p.P3123S | Missense Mutation (SNP) | VAF 154/357 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs150068835, COSV57220664; called by muse, mutect2, varscan2
- ALDH7A1 | c.341T>C p.V114A | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68629378; called by muse, mutect2, varscan2
- ALLC | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 109/172 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as COSV52996104; called by muse, mutect2, varscan2
- ALOX15 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.977); catalogued as rs1327529116, COSV53398975; called by muse, mutect2, varscan2
- ALOXE3 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV58554928; called by muse, mutect2, varscan2
- AMPD3 | c.157G>A p.E53K (on ENST00000396553 / NM_001025389.2; = p.E62K on NM_000480.3) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV67331563; called by muse, mutect2, varscan2
- ANGPTL5 | c.1034G>A p.G345D | Missense Mutation (SNP) | VAF 96/228 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369497815, COSV57532523; called by muse, mutect2, varscan2
- ANK2 | c.11225C>T p.P3742L | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.493); catalogued as rs753748906, COSV52172556; called by muse, mutect2, varscan2
- ANK3 | c.9175G>A p.E3059K | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs868622451, COSV55067533; called by muse, mutect2, varscan2
- ANK3 | c.6966G>A p.M2322I | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.024); catalogued as COSV55067544; called by muse, mutect2, varscan2
- ANK3 | c.2188G>A p.G730R | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs748974513, COSV55067557; called by muse, mutect2, varscan2
- ANKFN1 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 180/287 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59452488; called by muse, mutect2, varscan2
- ANKRD30A | c.3224T>G p.I1075R (on ENST00000611781; = p.I1019R on NM_052997.2) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV64614817, COSV64616026; called by muse, mutect2, varscan2
- ANO4 | c.2513G>A p.R838Q (on ENST00000392977 / NM_001286615.2; = p.R803Q on NM_178826.4) | Missense Mutation (SNP) | VAF 90/203 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.202); catalogued as rs778005685, COSV54596564, COSV54598541; called by muse, varscan2
- ANO5 | c.2687C>T p.A896V | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV61087416; called by muse, mutect2, varscan2
- AOC1 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as COSV62867057; called by muse, mutect2, varscan2
- ARHGAP10 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV60602334; called by muse, mutect2, varscan2
- ARHGAP22 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50955569; called by muse, mutect2, varscan2
- ARHGAP25 | c.1132C>T p.R378* (on ENST00000409202 / NM_001007231.3; = p.R370* on NM_014882.3) | Nonsense Mutation (SNP) | VAF 67/169 reads (40%) | catalogued as rs754902466, COSV54900986, COSV99770984; called by muse, mutect2, varscan2
- ARHGEF37 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as COSV61369352; called by muse, mutect2, varscan2
- ARID5B | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1383005171, COSV54424455; called by muse, mutect2, varscan2
- ARPP21 | c.1370T>C p.V457A | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV51794584, COSV99492451; called by muse, mutect2, varscan2
- ARSK | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 172/388 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.09); catalogued as COSV66170015; called by muse, mutect2, varscan2
- ART1 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as COSV51705593; called by muse, mutect2, varscan2
- ASB5 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs768506681, COSV56672361, COSV99641542; called by muse, mutect2, varscan2
- ATP13A5 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 150/311 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV60869434; called by muse, mutect2, varscan2
- BAAT | c.1216C>T p.L406F | Missense Mutation (SNP) | VAF 85/134 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.26); catalogued as rs1426190263, COSV52289931, COSV52290066; called by muse, mutect2, varscan2
- BANK1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs774595865, COSV59846005; called by muse, mutect2, varscan2
- BAZ1B | c.3343C>T p.P1115S | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV59991182; called by muse, mutect2, varscan2
- BCL9 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 183/530 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1553204269, COSV52347096; called by muse, mutect2, varscan2
- BDP1 | c.5039G>A p.R1680K | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.297); catalogued as COSV62432587; called by muse, mutect2, varscan2
- BECN1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV64120990; called by muse, mutect2, varscan2
- BMP3 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV51083612; called by muse, mutect2, varscan2
- BRAP | c.1730dup p.S578Qfs*51 | Frame Shift Ins (INS) | VAF 23/65 reads (35%) | catalogued as rs1184461495; called by mutect2, pindel, varscan2
- BRINP1 | c.2113C>T p.R705C | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs868162786, COSV56305557; called by muse, mutect2, varscan2
- BRINP1 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); catalogued as COSV56294559; called by muse, mutect2, varscan2
- BRINP3 | c.1647G>A p.M549I | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.38); catalogued as rs1557963299, COSV66520672; called by muse, mutect2, varscan2
- BRSK1 | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV58668034; called by muse, mutect2, varscan2
- BSN | c.11195C>T p.P3732L | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.187); catalogued as rs777607881, COSV99608801; called by muse, mutect2, varscan2
- C2CD3 | c.233G>A p.R78K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV58095361; called by muse, mutect2, varscan2
- C3 | c.3394G>A p.G1132R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55576094; called by muse, mutect2, varscan2
- C5orf46 | c.51A>C p.L17F | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); catalogued as COSV59154253; called by muse, mutect2, varscan2
- C6 | c.2425G>A p.D809N | Missense Mutation (SNP) | VAF 111/239 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as rs758843180, COSV54707562; called by muse, mutect2, varscan2
- C7orf57 | c.295T>C p.S99P | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as COSV62363295; called by muse, mutect2, varscan2
- C9orf131 | c.1575G>A p.M525I | Missense Mutation (SNP) | VAF 162/342 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV56612398; called by muse, mutect2, varscan2
- CA10 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 73/114 reads (64%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.503); catalogued as COSV53358512; called by muse, mutect2, varscan2
- CABP7 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as COSV53363427; called by muse, mutect2, varscan2
- CABS1 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as rs756032770, COSV56733869; called by muse, mutect2, varscan2
- CACNA1C | c.3578C>T p.A1193V | Missense Mutation (SNP) | VAF 84/152 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV59741495; called by muse, mutect2, varscan2
- CADPS2 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV57372645; called by muse, mutect2, varscan2
- CAMKV | c.562+1G>A p.X188_splice | Splice Site (SNP) | VAF 17/33 reads (52%) | catalogued as COSV56556544; called by muse, varscan2
- CARMIL1 | c.3617C>T p.S1206L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs868768530, COSV61520295; called by muse, mutect2, varscan2
- CBY2 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60118943; called by muse, mutect2, varscan2
- CCDC102B | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV60134843; called by muse, mutect2
- CCDC116 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 65/123 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201966964, COSV53038221; called by muse, mutect2, varscan2
- CCDC141 | c.3911G>A p.G1304E | Missense Mutation (SNP) | VAF 112/165 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs865980981, COSV55377174; called by muse, mutect2, varscan2
- CCDC34 | c.845A>T p.N282I | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV60821172; called by muse, mutect2, varscan2
- CD163 | c.3412T>A p.S1138T | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.098); catalogued as COSV63134791; called by muse, mutect2, varscan2
- CD163 | c.2692G>A p.G898R | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.936); catalogued as COSV63129198; called by muse, mutect2, varscan2
- CD163 | c.2075C>T p.S692L | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs772938688, COSV63131535, COSV63134805; called by muse, mutect2, varscan2
- CD163 | c.1916G>A p.G639E | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.996); catalogued as COSV63134811; called by muse, mutect2, varscan2
- CD163L1 | c.2720C>T p.S907F | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58019648; called by muse, mutect2, varscan2
- CD163L1 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.192); catalogued as rs762788583, COSV58012022; called by muse, mutect2, varscan2
- CD247 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 101/327 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV62978366, COSV62979101; called by muse, mutect2, varscan2
- CD33 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV51800727, COSV51802918; called by muse, mutect2, varscan2
- CD5 | c.1328A>G p.N443S | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as COSV61718675; called by muse, mutect2, varscan2
- CD96 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs774695561, COSV51918926; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD96 | c.889C>T p.P297S (on ENST00000283285 / NM_198196.3; = p.P281S on NM_005816.5) | Missense Mutation (SNP) | VAF 81/189 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51918940; called by muse, mutect2, varscan2
- CDCP2 | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 33/74 reads (45%) | catalogued as COSV61284637; called by muse, varscan2
- CDH6 | c.274C>T p.L92F | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54064772, COSV54073669, COSV54075850; called by muse, mutect2, varscan2
- CDK5 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as rs781286909, COSV52524046; called by muse, mutect2, varscan2
- CDKAL1 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 75/99 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV51186053; called by muse, mutect2, varscan2
- CEACAM18 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV67283506; called by muse, mutect2
- CEMIP | c.2815G>A p.G939R | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs755638227, COSV54995926; called by muse, mutect2, varscan2
- CEP112 | c.2609T>C p.V870A (on ENST00000392769 / NM_001353127.1; = p.V126A on NM_001037325.3) | Missense Mutation (SNP) | VAF 46/69 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58066116; called by muse, mutect2, varscan2
- CERS6 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0.013); catalogued as COSV59832254, COSV59833149; called by muse, mutect2, varscan2
- CETN3 | c.175T>C p.F59L | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV51617564, COSV51617704; called by muse, mutect2, varscan2
- CFAP299 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs866257430, COSV63880963; called by muse, mutect2, varscan2
- CFAP54 | c.7115C>T p.S2372F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as rs894088687, COSV61570780; called by muse, mutect2, varscan2
- CFAP54 | c.7816G>A p.E2606K | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV61573243; called by muse, mutect2, varscan2
- CFTR | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs397508285, CM970261, COSV50069776; ClinVar: not provided; called by muse, mutect2, varscan2
- CHD2 | c.2123C>T p.S708F | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV67711369; called by muse, mutect2, varscan2
- CHST15 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 60/99 reads (61%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs199887555, COSV60560141, COSV60560330; called by muse, mutect2, varscan2
- CIZ1 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV52972996; called by muse, mutect2, varscan2
- CLCC1 | c.382A>T p.I128F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV56764495; called by muse, mutect2, varscan2
- CLEC4M | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV50218844; called by muse, mutect2, varscan2
- CLSTN2 | c.1531T>A p.F511I | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV71722517; called by muse, mutect2, varscan2
- CLVS1 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.456); catalogued as COSV57978401; called by muse, mutect2, varscan2
- CMA1 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.99); catalogued as rs755848834, COSV51625938; called by muse, mutect2, varscan2
- CNGA1 | c.1920C>G p.I640M | Missense Mutation (SNP) | VAF 84/178 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV62055232; called by muse, varscan2
- CNGB3 | c.893C>T p.T298I | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV100181136, COSV60693118; called by muse, mutect2, varscan2
- CNKSR1 | c.731T>C p.V244A | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV64163658; called by muse, mutect2, varscan2
- CNTNAP5 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV70495885; called by muse, mutect2, varscan2
- CNTRL | c.4110G>T p.K1370N | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV53049763; called by muse, mutect2, varscan2
- COBL | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV54350674; called by muse, mutect2, varscan2
- COG5 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV99772374; called by muse, mutect2, varscan2
- COG5 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.202); catalogued as COSV99772375, COSV99772495; called by muse, mutect2, varscan2
- COL11A1 | c.4779G>A p.M1593I | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as COSV62175697, COSV62177733; called by muse, mutect2, varscan2
- COL12A1 | c.7420A>C p.K2474Q | Missense Mutation (SNP) | VAF 62/71 reads (87%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV59400381; called by muse, mutect2, varscan2
- COL22A1 | c.4564C>T p.R1522C | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.659); catalogued as rs185123006, COSV57322173; called by muse, mutect2, varscan2
- COL22A1 | c.2755-1G>A p.X919_splice | Splice Site (SNP) | VAF 28/66 reads (42%) | catalogued as COSV57346059; called by muse, mutect2, varscan2
- COL22A1 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 51/210 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.673); catalogued as rs1298017320, COSV57346066; called by muse, mutect2, varscan2
- COL2A1 | c.1069-1G>A p.X357_splice | Splice Site (SNP) | VAF 5/16 reads (31%) | catalogued as COSV61532121; called by muse, mutect2, varscan2
- COL4A1 | c.2654G>A p.G885E | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65428164; called by muse, mutect2, varscan2
- COL4A4 | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV61633990; called by muse, mutect2, varscan2
- COL5A1 | c.1453A>G p.T485A | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.973); catalogued as COSV65671537; called by muse, mutect2, varscan2
- COL5A3 | c.4318C>T p.P1440S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV53414313; called by muse, mutect2, varscan2
- COL6A3 | c.2483C>T p.P828L | Missense Mutation (SNP) | VAF 272/468 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV55097442; called by muse, mutect2, varscan2
- COL6A5 | c.6796G>A p.E2266K (on ENST00000312481; = p.E2262K on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as rs1242504947, COSV55208131; called by muse, mutect2
- COL6A6 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs767981675, COSV62030092; called by muse, mutect2, varscan2
- COL9A2 | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs749736976, COSV65623344; called by muse, mutect2, varscan2
- CPS1 | c.4275-1G>A p.X1425_splice | Splice Site (SNP) | VAF 42/119 reads (35%) | catalogued as COSV51816328; called by muse, mutect2, varscan2
- CR1L | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 126/444 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as rs777986568, COSV54328298; called by muse, mutect2, varscan2
- CRB1 | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 181/298 reads (61%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as COSV66330452; called by muse, mutect2, varscan2
- CSMD1 | c.10601C>T p.S3534L (on ENST00000520002; = p.S3533L on NM_033225.6) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs764398530, COSV59336713; called by muse, mutect2
- CSMD1 | c.3941G>A p.G1314E (on ENST00000520002; = p.G1313E on NM_033225.6) | Missense Mutation (SNP) | VAF 138/290 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1416089699, COSV59333324; called by muse, mutect2
- CSMD3 | c.10471C>T p.P3491S (on ENST00000297405 / NM_001363185.1; = p.P3322S on NM_052900.3) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52236632; called by muse, mutect2, varscan2
- CST8 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.398); catalogued as COSV55671151; called by muse, varscan2
- CYB5R4 | c.202A>T p.K68* | Nonsense Mutation (SNP) | VAF 52/57 reads (91%) | catalogued as COSV63746868; called by muse, mutect2, varscan2
- CYP2C18 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 83/183 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs770145786, COSV53669438; called by muse, mutect2, varscan2
- CYP4A11 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 80/185 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV60224358; called by muse, mutect2, varscan2
- CYP4B1 | c.773-1G>A p.X258_splice | Splice Site (SNP) | VAF 29/55 reads (53%) | catalogued as COSV54724531; called by muse, mutect2, varscan2
- CYP4X1 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64150584; called by muse, mutect2, varscan2
- CYP8B1 | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs536175564, COSV60225587; called by muse, mutect2, varscan2
- DDI2 | c.230A>T p.K77M | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.777); catalogued as COSV60780387; called by muse, mutect2, varscan2
- DEFB118 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 89/158 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV53620130; called by muse, mutect2, varscan2
- DES | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 75/118 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV64660663; called by muse, mutect2, varscan2
- DGAT2L6 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 56/59 reads (95%) | catalogued as COSV60718178; called by muse, mutect2, varscan2
- DGKI | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 239/436 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV55960543; called by muse, mutect2, varscan2
- DHX8 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 100/237 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as COSV52254747; called by muse, mutect2, varscan2
- DIO1 | c.319A>G p.I107V | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV50778074; called by muse, mutect2, varscan2
- DKK2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 115/196 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53393923; called by muse, mutect2, varscan2
- DLEC1 | c.1876C>T p.L626F | Missense Mutation (SNP) | VAF 71/138 reads (51%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.751); catalogued as COSV57302421; called by muse, mutect2, varscan2
- DLG2 | c.1999C>T p.L667F | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV54662747; called by muse, mutect2, varscan2
- DNAH2 | c.5674G>A p.E1892K | Missense Mutation (SNP) | VAF 28/29 reads (97%) | SIFT tolerated (0.3); PolyPhen benign (0.405); catalogued as COSV66722187; called by muse, mutect2, varscan2
- DNAH5 | c.5833G>A p.E1945K | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54223692; called by muse, mutect2, varscan2
- DNAH5 | c.3055C>T p.P1019S | Missense Mutation (SNP) | VAF 111/244 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs753792086, COSV54237606; called by muse, mutect2, varscan2
- DNAH7 | c.4934T>C p.L1645S | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs760931476, COSV56773578; called by muse, mutect2, varscan2
- DNAH8 | c.6745G>A p.E2249K | Missense Mutation (SNP) | VAF 116/193 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as COSV59429023; called by muse, mutect2, varscan2
- DNAH9 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 46/49 reads (94%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV52359825; called by muse, mutect2, varscan2
- DOCK3 | c.2569C>T p.P857S | Missense Mutation (SNP) | VAF 130/315 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV56508149; called by muse, mutect2, varscan2
- DPYS | c.1236G>A p.R412= | Splice Region (SNP) | VAF 42/162 reads (26%) | catalogued as COSV100679786, COSV100679807, COSV100679871; called by muse, mutect2, varscan2
- DROSHA | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs779587523, COSV100757656; called by muse, mutect2, varscan2
- DROSHA | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs1263164551, COSV100757658; called by muse, mutect2, varscan2
- DSCAM | c.5455G>A p.E1819K | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV68030907; called by muse, mutect2, varscan2
- DSCAM | c.4705G>A p.D1569N | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV68030910; called by muse, mutect2, varscan2
- DSP | c.7367C>T p.S2456L | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV65793877; called by muse, mutect2, varscan2
- DSPP | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.084); catalogued as COSV56812799; called by muse, mutect2, varscan2
- DST | c.21516G>A p.E7172= (on ENST00000361203 / NM_001374722.1; = p.E4869= on NM_015548.5) | Splice Region (SNP) | VAF 17/60 reads (28%) | catalogued as COSV55025206; called by muse, mutect2, varscan2
- DTNB | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as COSV56479904; called by muse, mutect2, varscan2
- DUOX2 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as COSV59908935; called by muse, mutect2, varscan2
- DUSP13 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV57814816; called by muse, mutect2, varscan2
- DUSP8 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV59030650; called by muse, mutect2, varscan2
- E2F5 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 103/136 reads (76%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV56275546; called by muse, mutect2, varscan2
- EBF2 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.184); catalogued as COSV68775882; called by muse, mutect2, varscan2
- EBF3 | c.1189A>G p.N397D (on ENST00000355311 / NM_001375392.1; = p.N388D on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV62477427; called by muse, mutect2, varscan2
- EFL1 | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0.021); catalogued as COSV51607566; called by muse, mutect2, varscan2
- EGFL6 | c.607C>T p.H203Y | Missense Mutation (SNP) | VAF 93/97 reads (96%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV63634412; called by muse, mutect2, varscan2
- EGR1 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV53520376; called by muse, mutect2, varscan2
- ELMO1 | c.1613A>T p.E538V | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV60312479; called by muse, mutect2
- ENTHD1 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57322358; called by muse, mutect2, varscan2
- ENTPD1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.075); catalogued as rs1202376698, COSV64602850; called by muse, mutect2, varscan2
- EP400 | c.4459C>T p.P1487S | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.059); catalogued as COSV57776391; called by muse, mutect2, varscan2
- EPYC | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754135032, COSV53798497; called by muse, mutect2, varscan2
- ERICH3 | c.3026C>T p.S1009L | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs1365373663, COSV58605892; called by muse, mutect2, varscan2
- ERVFRD-1 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.823); catalogued as rs756242354, COSV65368765; called by muse, mutect2, varscan2
- ESPN | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 68/134 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.277); catalogued as COSV64704932; called by muse, mutect2, varscan2
- ESPN | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64704937; called by muse, varscan2
- EXOC1 | c.2108C>T p.T703I | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV62121048; called by muse, mutect2, varscan2
- EXOSC8 | c.673G>C p.V225L | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV53509600; called by muse, mutect2, varscan2
- EXTL3 | c.2277G>A p.R759= | Splice Region (SNP) | VAF 92/196 reads (47%) | catalogued as COSV55038853; called by muse, mutect2, varscan2
- F2RL1 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 57/113 reads (50%) | catalogued as rs369747168; called by muse, mutect2, varscan2
- FAM120A | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.536); catalogued as rs1349235953, COSV52907323; called by muse, mutect2, varscan2
- FAM13C | c.1112G>A p.R371K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1207454754, COSV53251776; called by muse, mutect2, varscan2
- FAM171A1 | c.1954G>A p.G652S | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.879); catalogued as COSV65317508; called by muse, mutect2, varscan2
- FANCA | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.631); catalogued as rs145334278; called by muse, varscan2
- FASTK | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); catalogued as rs746916318, COSV52540975; called by muse, mutect2, varscan2
- FAT3 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.077); catalogued as rs531760483, COSV53076064; called by muse, mutect2, varscan2
- FAT3 | c.13387C>T p.P4463S | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV53139145; called by muse, mutect2, varscan2
- FAT4 | c.12452C>T p.A4151V | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV58695553; called by muse, mutect2, varscan2
- FBN3 | c.4582G>A p.G1528S | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54465588; called by muse, mutect2, varscan2
- FCGR1A | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV100977292, COSV64985736; called by muse, mutect2, varscan2
- FCGR3A | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 61/360 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100914664; called by muse, mutect2, varscan2
- FCGR3A | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 63/360 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777467556, COSV63460569; called by muse, mutect2, varscan2
- FER1L6 | c.4247C>T p.P1416L | Missense Mutation (SNP) | VAF 210/302 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67551283; called by muse, mutect2, varscan2
- FGA | c.2183T>C p.L728S | Missense Mutation (SNP) | VAF 121/249 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57398050, COSV57402375; called by muse, mutect2, varscan2
- FGF16 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 25/25 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868993594, COSV71546158; called by muse, mutect2, varscan2
- FGFR1 | c.1343G>T p.R448L (on ENST00000447712 / NM_023110.3; = p.R446L on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs758138124, COSV58338600, COSV58340503; called by mutect2, varscan2
- FGG | c.1088A>G p.N363S | Missense Mutation (SNP) | VAF 85/212 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60195304, COSV60195933; called by muse, mutect2, varscan2
- FILIP1 | c.2537C>T p.P846L | Missense Mutation (SNP) | VAF 109/114 reads (96%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs765584991, COSV52732911; called by muse, mutect2, varscan2
- FLRT1 | c.72G>A p.M24I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV55363386; called by muse, mutect2, varscan2
- FLRT2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58145402, COSV58147567; called by muse, mutect2, varscan2
- FLT3 | c.1838G>A p.G613E | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV54060386; called by muse, mutect2, varscan2
- FMN2 | c.2882G>A p.G961E | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.934); catalogued as rs1387407429, COSV100143926, COSV60439191; called by muse, mutect2, varscan2
- FOXP4 | c.1399C>T p.R467W (on ENST00000307972 / NM_001012426.1; = p.R454W on NM_138457.3) | Missense Mutation (SNP) | VAF 160/293 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57219469; called by muse, mutect2, varscan2
- FPR3 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs1379995512, COSV59330775; called by muse, mutect2, varscan2
- FREM1 | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 86/92 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66526318; called by muse, mutect2, varscan2
- FREM2 | c.7243G>A p.D2415N | Missense Mutation (SNP) | VAF 93/196 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as rs563216892, COSV54832421, COSV54837001; called by muse, mutect2, varscan2
- FRMD3 | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 81/294 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as COSV58461864; called by muse, mutect2, varscan2
- FRMPD2 | c.2560G>A p.E854K | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs752089946, COSV100564016, COSV59720132; called by muse, mutect2, varscan2
- FRMPD4 | c.917A>C p.E306A | Missense Mutation (SNP) | VAF 28/32 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV66214718, COSV66218639; called by muse, mutect2, varscan2
- FSTL3 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV51261744; called by muse, mutect2, varscan2
- FYB2 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1557600991, COSV58586757; called by muse, mutect2, varscan2
- FZR1 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 61/110 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1251805158, COSV58051483; called by muse, mutect2, varscan2
- GABRG1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV54957506; called by muse, mutect2, varscan2
- GBP1 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 250/617 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV65083947; called by muse, mutect2, varscan2
- GDPD4 | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 48/91 reads (53%) | catalogued as COSV60019458; called by muse, mutect2, varscan2
- GEN1 | c.1822C>T p.H608Y | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV58057465; called by muse, mutect2, varscan2
- GFRAL | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 74/227 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as rs757540959, COSV61231407, COSV61232771; called by muse, mutect2, varscan2
- GIMAP6 | c.265A>C p.K89Q | Missense Mutation (SNP) | VAF 163/247 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as COSV61034022; called by muse, mutect2, varscan2
- GIMAP7 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV57959822; called by muse, mutect2, varscan2
- GKAP1 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs749922734, COSV100897665; called by muse, mutect2, varscan2
- GKAP1 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100897666; called by muse, mutect2, varscan2
- GNAQ | c.899G>A p.R300K | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs760869735, COSV54118464; called by muse, mutect2, varscan2
- GNB3 | c.12G>A p.M4I | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1555123304, COSV51833248; called by muse, mutect2, varscan2
- GPATCH2L | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.439); catalogued as COSV55049614; called by muse, mutect2, varscan2
- GPR141 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 100/162 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759565313, COSV57731278, COSV57732248; called by muse, mutect2, varscan2
- GPR148 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 134/242 reads (55%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs768297521, COSV59308755; called by muse, mutect2, varscan2
- GPR174 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 158/169 reads (93%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as rs752024773, COSV52132444; called by muse, mutect2, varscan2
- GPR65 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs762323389, COSV50862678; called by muse, mutect2, varscan2
- GPR68 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773867347, COSV53176078, COSV53177210; called by muse, mutect2, varscan2
- GPR87 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756283406, COSV53463697; called by muse, mutect2, varscan2
- GRIN3B | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV52261580; called by muse, mutect2, varscan2
- GRM5 | c.2414C>T p.S805L | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1296626989, COSV59614394; called by muse, mutect2, varscan2
- GRM8 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV58843582; called by muse, mutect2, varscan2
- GTF2B | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 34/109 reads (31%) | catalogued as rs772494214, COSV65137090; called by muse, mutect2, varscan2
- GTSF1 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 86/197 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV59938243; called by muse, mutect2, varscan2
- H3-3B | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV54667108; called by muse, mutect2, varscan2
- HARS1 | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 40/104 reads (38%) | catalogued as COSV56907987; called by muse, mutect2, varscan2
- HARS1 | c.630G>A p.K210= | Splice Region (SNP) | VAF 19/61 reads (31%) | catalogued as rs202162444, COSV56908000; called by muse, mutect2, varscan2
- HCRTR2 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 104/156 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866684522, COSV63795299; called by muse, mutect2, varscan2
- HDC | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51074108; called by muse, mutect2, varscan2
- HFM1 | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV54031600; called by muse, mutect2, varscan2
- HGF | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.22); PolyPhen benign (0.424); catalogued as COSV55952685; called by muse, mutect2, varscan2
- HHIP | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 85/172 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.258); catalogued as COSV56841444; called by muse, mutect2, varscan2
- HIF1A | c.785T>C p.L262S | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60190021; called by muse, mutect2, varscan2
- HIRA | c.356A>G p.E119G | Missense Mutation (SNP) | VAF 78/159 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54276907; called by muse, mutect2, varscan2
- HMGB4 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as rs747612103, COSV53931028; called by muse, mutect2, varscan2
- HNRNPAB | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV57425105; called by muse, mutect2, varscan2
- HORMAD1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV59272124; called by muse, mutect2, varscan2
- HSD17B6 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59108212; called by muse, mutect2, varscan2
- HSPA14 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 97/212 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1276826911, COSV65684657; called by muse, mutect2, varscan2
- HSPA4L | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 93/208 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV56546677; called by muse, mutect2, varscan2
- HTR3D | c.1097G>A p.G366E (on ENST00000382489 / NM_001163646.2; = p.G191E on NM_182537.3) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.096); catalogued as rs764286325, COSV61913836; called by muse, mutect2, varscan2
- IDO2 | c.928G>A p.D310N (on ENST00000389060; = p.D323N on NM_194294.2) | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as COSV58426889; called by muse, mutect2, varscan2
- IFT122 | c.2572C>T p.P858S (on ENST00000348417 / NM_052989.3; = p.P799S on NM_018262.4) | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56205163; called by muse, mutect2, varscan2
- IGHV2-70 | c.68T>G p.L23W | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs189702615; called by muse, mutect2, varscan2
- IGHV3-15 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.894); catalogued as rs782200062; called by muse, mutect2, varscan2
- IGHV4-39 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as rs753404788; called by muse, mutect2, varscan2
- IGSF1 | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 84/93 reads (90%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.968); catalogued as COSV63838582; called by muse, mutect2, varscan2
- IKZF3 | c.1487C>T p.S496L | Missense Mutation (SNP) | VAF 95/203 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754805856, COSV53104022; called by muse, mutect2, varscan2
- IKZF3 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs867642116, COSV53104034; called by muse, mutect2, varscan2
- IL12RB1 | c.221G>A p.S74N | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV59098124; called by muse, mutect2, varscan2
- IL20RA | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57356793; called by muse, mutect2, varscan2
- IL21 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as COSV52646444; called by muse, mutect2, varscan2
- IL21R | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.031); catalogued as COSV61971443; called by muse, mutect2, varscan2
- IMPG2 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 76/142 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV51981532; called by muse, mutect2, varscan2
- INTS11 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs369581497; called by muse, mutect2, varscan2
- INTS5 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 20/49 reads (41%) | catalogued as COSV100399675; called by muse, mutect2, varscan2
- IPO4 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 238/568 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV55780776; called by muse, mutect2, varscan2
- ISL2 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV51958487; called by muse, mutect2, varscan2
- ITGA3 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50320269; called by muse, mutect2, varscan2
- ITGA8 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.461); catalogued as COSV65223985; called by muse, mutect2, varscan2
- ITGB2 | c.134G>A p.W45* | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | catalogued as COSV100185929; called by muse, mutect2, varscan2
- ITGB7 | c.1582C>T p.R528W | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs942846386, COSV57237915; called by muse, mutect2, varscan2
- ITPK1 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV50897073; called by muse, mutect2, varscan2
- ITPRIPL2 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as COSV67347862; called by muse, mutect2, varscan2
- ITSN1 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 34/77 reads (44%) | catalogued as rs1355286586, COSV66080567; called by muse, mutect2, varscan2
- JAK3 | c.145T>G p.L49V | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.83); PolyPhen benign (0.013); catalogued as COSV71686587; called by muse, mutect2, varscan2
- JAKMIP2 | c.2429G>A p.G810E | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as COSV54603999; called by muse, mutect2, varscan2
- JCAD | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as rs576082696, COSV64757719; called by muse, mutect2, varscan2
- KANK1 | c.3503A>G p.Y1168C | Missense Mutation (SNP) | VAF 105/112 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63213667; called by muse, mutect2, varscan2
- KANSL2 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.663); catalogued as rs745600847, COSV63479983; called by muse, mutect2, varscan2
- KBTBD6 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV65271586; called by muse, mutect2, varscan2
- KCNC1 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.141); catalogued as COSV56395996; called by muse, mutect2, varscan2
- KCNH4 | c.3001A>G p.T1001A | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV52919102; called by muse, mutect2, varscan2
- KCNT2 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as COSV54062653; called by muse, varscan2
- KCNT2 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs370788660; called by muse, mutect2, varscan2
- KDR | c.887G>A p.G296D | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV55769581, COSV55769617; called by muse, mutect2, varscan2
- KEL | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs771153437, COSV62336309; called by muse, mutect2, varscan2
- KHDRBS2 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55470304; called by muse, mutect2, varscan2
- KIAA0232 | c.2443C>T p.P815S | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.742); catalogued as COSV56926975; called by muse, mutect2, varscan2
- KIAA0825 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56955449; called by muse, mutect2, varscan2
- KIDINS220 | c.4924C>T p.R1642W | Missense Mutation (SNP) | VAF 70/120 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs773095081, COSV56755745; called by muse, mutect2, varscan2
- KIF2C | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100945790, COSV64765041; called by muse, mutect2, varscan2
- KIF4B | c.668G>A p.R223K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as rs1554107070, COSV70530285; called by muse, mutect2, varscan2
- KLHDC7A | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV68770304; called by muse, mutect2, varscan2
- KLHL36 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs535890864, COSV50720375; called by muse, mutect2, varscan2
- KLHL6 | c.1145C>T p.S382L | Missense Mutation (SNP) | VAF 113/240 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58067780; called by muse, mutect2, varscan2
- KLK15 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56825966; called by muse, mutect2, varscan2
- KMT2B | c.7396G>A p.G2466S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55820984; called by muse, mutect2
- KNTC1 | c.5724A>T p.K1908N | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV61079130, COSV61081721; called by muse, mutect2, varscan2
- KRT28 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs200406506, COSV60683823, COSV60684962; called by muse, mutect2, varscan2
- KRT78 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs375440936; called by muse, mutect2, varscan2
- KRTAP4-5 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV58352799; called by muse, mutect2, varscan2
- KRTAP9-2 | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1369093548, COSV66646863; called by muse, varscan2
- LAMA2 | c.5932C>T p.L1978F | Missense Mutation (SNP) | VAF 40/46 reads (87%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs368316367, COSV70351327; called by muse, mutect2, varscan2
- LAMA2 | c.7724G>A p.R2575K | Missense Mutation (SNP) | VAF 85/96 reads (89%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.577); catalogued as COSV70351328; called by muse, mutect2, varscan2
- LIFR | c.705G>A p.W235* | Nonsense Mutation (SNP) | VAF 41/68 reads (60%) | catalogued as COSV54693915; called by muse, mutect2, varscan2
- LILRA2 | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0.017); catalogued as COSV52193844; called by muse, mutect2, varscan2
- LILRA5 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 76/139 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.676); catalogued as rs892298574, COSV56643914; called by muse, mutect2, varscan2
- LILRB1 | c.503G>A p.S168N (on ENST00000427581; = p.S132N on NM_006669.6) | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV61116540, COSV61119409; called by muse, varscan2
- LILRB5 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as COSV60256405; called by muse, mutect2, varscan2
- LIMS2 | c.68C>T p.S23F (on ENST00000355119 / NM_001161403.3; = p.S47F on NM_017980.4) | Missense Mutation (SNP) | VAF 85/207 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs138668344; called by muse, mutect2, varscan2
- LIPH | c.1239G>A p.M413I | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV56183018; called by muse, mutect2, varscan2
- LPAR1 | c.641A>G p.N214S | Missense Mutation (SNP) | VAF 97/157 reads (62%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.679); catalogued as COSV62689933; called by muse, mutect2, varscan2
- LPO | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 90/338 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV51860439; called by muse, mutect2, varscan2
- LRIG1 | c.2722T>A p.W908R | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.46); catalogued as COSV99833907; called by muse, mutect2, varscan2
- LRP1B | c.12415C>T p.R4139* | Nonsense Mutation (SNP) | VAF 87/149 reads (58%) | catalogued as rs1263766326, COSV67232067, COSV67287432; called by muse, mutect2, varscan2
- LRP2 | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 92/141 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55561555; called by muse, mutect2
- LRP6 | c.4339A>T p.S1447C | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.789); catalogued as COSV99743579; called by muse, mutect2, varscan2
- LRRC30 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as rs867952372, COSV67301986, COSV67302511; called by muse, mutect2, varscan2
- LRRC3B | c.72G>A p.M24I | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV67521784; called by muse, mutect2, varscan2
- LRRC4C | c.945G>A p.W315* | Nonsense Mutation (SNP) | VAF 36/65 reads (55%) | catalogued as rs151083424, COSV53427812; called by muse, mutect2, varscan2
- LRRC7 | c.4654G>A p.E1552K (on ENST00000651989 / NM_001370785.2; = p.E1472K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.942); catalogued as COSV50507359, COSV99226034; called by muse, mutect2, varscan2
- LRRN1 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 118/290 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.052); catalogued as COSV60014836; called by muse, mutect2, varscan2
- LRRN1 | c.1771G>A p.D591N | Missense Mutation (SNP) | VAF 137/307 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV60014843; called by muse, mutect2, varscan2
- LTBP1 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 234/362 reads (65%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs377541507; called by muse, mutect2, varscan2
- LUM | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57128607; called by muse, mutect2, varscan2
- LZTFL1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV56111783; called by muse, mutect2, varscan2
- MAB21L4 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs768362452, COSV56743981; called by muse, mutect2, varscan2
- MACROH2A1 | c.560C>T p.S187F (on ENST00000510038; = p.S186F on NM_004893.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56896629; called by muse, mutect2, varscan2
- MAGEC1 | c.2188C>T p.P730S | Missense Mutation (SNP) | VAF 104/108 reads (96%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.048); catalogued as rs771890346, COSV53573197; called by muse, mutect2, varscan2
- MAL2 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 117/257 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs745631374, COSV52661872; called by muse, mutect2, varscan2
- MAN1A1 | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 79/85 reads (93%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as COSV63788191; called by muse, mutect2, varscan2
- MAN2A1 | c.1577+2T>C p.X526_splice | Splice Site (SNP) | VAF 16/38 reads (42%) | catalogued as COSV54854632; called by muse, mutect2, varscan2
- MAPT | c.1742C>T p.P581L (on ENST00000262410 / NM_001377265.1; = p.P189L on NM_005910.5) | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV52242850; called by muse, mutect2, varscan2
- MARCHF11 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.06); catalogued as rs1488229935, COSV60131288; called by muse, mutect2, varscan2
- MAST4 | c.1582C>T p.P528S (on ENST00000403625 / NM_001164664.2; = p.P339S on NM_015183.3) | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55114065; called by muse, mutect2, varscan2
- MCMBP | c.144+2T>C p.X48_splice | Splice Site (SNP) | VAF 45/75 reads (60%) | catalogued as COSV63509649; called by muse, mutect2, varscan2
- MECOM | c.1586C>T p.S529L (on ENST00000468789 / NM_001105078.4; = p.S717L on NM_004991.4) | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1169063502, COSV52966929; called by muse, mutect2, varscan2
- MED12L | c.6169C>T p.R2057* | Nonsense Mutation (SNP) | VAF 71/140 reads (51%) | catalogued as rs371833156, COSV56372941; called by muse, mutect2, varscan2
- MED24 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.689); catalogued as COSV62419648; called by muse, mutect2, varscan2
- MEI1 | c.1639C>T p.L547F | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55904707; called by muse, mutect2, varscan2
- MET | c.3443G>A p.R1148Q | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as rs761808213, CM068008, COSV59258286; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MET | c.4067A>G p.Y1356C | Missense Mutation (SNP) | VAF 148/236 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59264499; called by muse, mutect2
- MFSD9 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV51492822; called by muse, mutect2, varscan2
- MGAM | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 61/219 reads (28%) | catalogued as rs781972778, COSV71884941; called by muse, mutect2, varscan2
- MGAM | c.2699A>T p.N900I | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV72075060; called by muse, mutect2, varscan2
- MIOS | c.1831G>A p.V611I | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV100402830; called by muse, mutect2, varscan2
- MIOS | c.1832T>A p.V611D | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100402833; called by muse, mutect2, varscan2
- MLH1 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.752); catalogued as COSV51614229; called by mutect2, varscan2
- MMP20 | c.661T>C p.F221L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV52776704; called by muse, mutect2, varscan2
- MOV10 | c.2879A>T p.N960I | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV53518442; called by muse, mutect2, varscan2
- MPL | c.538A>T p.T180S | Missense Mutation (SNP) | VAF 77/144 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV65245656; called by muse, mutect2, varscan2
- MROH2B | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV68181244; called by muse, mutect2, varscan2
- MRPS10 | c.462T>G p.D154E | Missense Mutation (SNP) | VAF 83/141 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV50002838; called by muse, mutect2, varscan2
- MTNR1A | c.485A>G p.N162S | Missense Mutation (SNP) | VAF 55/95 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs1199505841, COSV56156856; called by muse, mutect2, varscan2
- MTNR1B | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 82/208 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as rs878989131, COSV57068730; called by muse, mutect2, varscan2
- MTOR | c.7448-1G>T p.X2483_splice | Splice Site (SNP) | VAF 49/112 reads (44%) | catalogued as COSV63874370; called by muse, mutect2, varscan2
- MTRES1 | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 56/60 reads (93%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV60968382; called by muse, mutect2, varscan2
- MUC16 | c.35675C>T p.T11892I | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.148); catalogued as rs912433537, COSV67478081; called by muse, mutect2, varscan2
- MUC16 | c.33938C>T p.P11313L | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.708); catalogued as rs267605784, COSV67478086; called by muse, mutect2, varscan2
- MUC16 | c.19223G>A p.R6408K | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV67456113; called by muse, mutect2, varscan2
- MUC16 | c.6885G>A p.W2295* | Nonsense Mutation (SNP) | VAF 25/45 reads (56%) | catalogued as COSV67446866; called by muse, mutect2, varscan2
- MUC16 | c.3638G>A p.G1213E | Missense Mutation (SNP) | VAF 108/250 reads (43%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.336); catalogued as rs867583578, COSV67456295; called by muse, mutect2, varscan2
- MUC16 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as COSV67452327, COSV67462355; called by muse, mutect2, varscan2
- MXRA5 | c.6720G>A p.M2240I | Missense Mutation (SNP) | VAF 79/86 reads (92%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.791); catalogued as COSV54239870; called by muse, mutect2, varscan2
- MYBPC3 | c.1022G>A p.G341D | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1339369055, COSV57030265; called by muse, mutect2, varscan2
- MYCBP2 | c.1012C>T p.L338F (on ENST00000357337; = p.L376F on NM_015057.5) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62027980; called by muse, varscan2
- MYCBPAP | c.1555G>A p.G519R | Missense Mutation (SNP) | VAF 70/118 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355834942, COSV60409608; called by muse, mutect2, varscan2
- MYF5 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.175); catalogued as COSV57355691; called by muse, mutect2, varscan2
- MYH2 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 71/92 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs752344685, COSV55442264; called by muse, mutect2, varscan2
- MYH4 | c.3910C>T p.Q1304* | Nonsense Mutation (SNP) | VAF 69/74 reads (93%) | catalogued as COSV55121899; called by muse, mutect2, varscan2
- MYO16 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51780718; called by muse, mutect2, varscan2
- MYO18B | c.5704G>A p.D1902N | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59140474; called by muse, mutect2, varscan2
- MYO5C | c.2470C>T p.R824C | Missense Mutation (SNP) | VAF 159/371 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as rs1451955920, COSV55903122; called by muse, mutect2, varscan2
- MYO7A | c.1575A>T p.L525F | Missense Mutation (SNP) | VAF 87/192 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV68685596; called by muse, mutect2, varscan2
- MYOD1 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51454462; called by muse, mutect2, varscan2
- MYOM1 | c.1753C>T p.R585* | Nonsense Mutation (SNP) | VAF 43/94 reads (46%) | catalogued as rs770496510, COSV55291962; called by muse, mutect2, varscan2
- MYT1 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV60509146; called by muse, mutect2, varscan2
- MYT1L | c.3026G>A p.G1009E | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101217473, COSV67703614; called by muse, mutect2, varscan2
- NAXD | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as rs1163607795, COSV99959719; called by muse, mutect2, varscan2
- NCF2 | c.612C>T p.V204= | Splice Region (SNP) | VAF 43/124 reads (35%) | catalogued as rs772322729, COSV62316013; called by muse, mutect2, varscan2
- NCKAP1 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as COSV62942033; called by muse, mutect2, varscan2
- NCKAP5 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 82/163 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as COSV58457586; called by muse, mutect2, varscan2
- NCOA3 | c.3269C>T p.P1090L | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV59070584; called by muse, mutect2, varscan2
- NCOR2 | c.5075C>T p.S1692L | Missense Mutation (SNP) | VAF 97/219 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62300368; called by muse, mutect2, varscan2
- NCR2 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66100912; called by muse, mutect2, varscan2
- NEFM | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); catalogued as rs865855175, COSV55333250; called by muse, mutect2, varscan2
- NFIA | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 127/320 reads (40%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as rs1310469834, COSV64540422; called by muse, mutect2, varscan2
- NHLRC1 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 89/133 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV61481679; called by muse, mutect2, varscan2
- NIPBL | c.979A>G p.K327E | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.045); catalogued as COSV56957419; called by muse, mutect2, varscan2
- NLRC3 | c.2206G>A p.D736N | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs774771502, COSV57093015; called by muse, mutect2, varscan2
- NLRP11 | c.1580G>A p.G527E | Missense Mutation (SNP) | VAF 97/231 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1272202551, COSV64088144; called by muse, mutect2, varscan2
- NME8 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 53/83 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV52249719; called by muse, mutect2, varscan2
- NOS1 | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV57610370; called by muse, varscan2
- NPAP1 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 44/54 reads (81%) | SIFT tolerated (0.17); PolyPhen benign (0.3); catalogued as COSV61508778; called by muse, mutect2, varscan2
- NPAP1 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 126/147 reads (86%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs865895928, COSV61506356; called by muse, mutect2, varscan2
- NPPA | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.15); catalogued as COSV56741541; called by muse, mutect2, varscan2
- NPY1R | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 28/51 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV56714041; called by muse, mutect2, varscan2
- NRG3 | c.1988G>A p.R663Q (on ENST00000404547 / NM_001370084.1; = p.R639Q on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.584); catalogued as rs201611752, COSV64546973; called by muse, mutect2, varscan2
- NUP205 | c.1366C>T p.H456Y | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as rs747312318, COSV53661983; called by muse, mutect2, varscan2
- NUP98 | c.4424G>T p.G1475V (on ENST00000359171 / NM_001365126.1; = p.G1458V on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as rs1410356079, COSV61434889; called by muse, mutect2, varscan2
- NWD1 | c.1767C>T p.S589= | Splice Region (SNP) | VAF 14/32 reads (44%) | catalogued as COSV60345990; called by muse, mutect2, varscan2
- OBSCN | c.9758G>A p.R3253Q | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs759315645, COSV52794713; called by muse, mutect2, varscan2
- OBSCN | c.20405C>T p.P6802L | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs920126465, COSV62737138; called by muse, mutect2, varscan2
- OLAH | c.271C>T p.Q91* (on ENST00000378228 / NM_001039702.3; = p.Q144* on NM_018324.3) | Nonsense Mutation (SNP) | VAF 74/190 reads (39%) | catalogued as COSV65493161; called by muse, mutect2, varscan2
- OMA1 | c.623T>G p.V208G | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs552327271, COSV62255130, COSV62256043; called by muse, mutect2, varscan2
- OPTN | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV99537582; called by muse, mutect2, varscan2
- OR11G2 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778995976, COSV62132702; called by muse, mutect2, varscan2
- OR11L1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs202119268, COSV63314778; called by muse, mutect2, varscan2
- OR13C2 | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 115/150 reads (77%) | SIFT tolerated (0.34); PolyPhen benign (0.049); catalogued as COSV73377742; called by muse, mutect2, varscan2
- OR1L4 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 159/1003 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.058); catalogued as COSV52340918; called by muse, varscan2
- OR2A12 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 61/236 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV68821018; called by muse, mutect2, varscan2
- OR2A14 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 156/713 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV68718398; called by muse, mutect2
- OR2D2 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 66/129 reads (51%) | catalogued as COSV55057564; called by muse, mutect2, varscan2
- OR2H2 | c.899G>A p.R300K | Missense Mutation (SNP) | VAF 65/101 reads (64%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV63543389; called by muse, mutect2, varscan2
- OR2L13 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV63551105, COSV63551708; called by muse, varscan2
- OR2L13 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV63556476; called by muse, varscan2
- OR4C13 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.098); catalogued as rs1490429110, COSV101634204; called by muse, mutect2, varscan2
- OR4D6 | c.748C>T p.H250Y | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.3); catalogued as COSV55660248; called by muse, mutect2, varscan2
- OR4F6 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 160/316 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV61027198; called by muse, mutect2, varscan2
- OR4K15 | c.701C>T p.S234F (on ENST00000305051; = p.S210F on NM_001005486.1) | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV59300274; called by muse, mutect2, varscan2
- OR4X2 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV56582974; called by muse, varscan2
- OR56B1 | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 91/193 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57723460; called by muse, mutect2, varscan2
- OR5D16 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 48/80 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV65721443; called by muse, mutect2, varscan2
- OR5M10 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.181); catalogued as rs1319042945, COSV73242333, COSV73242415; called by muse, mutect2, varscan2
- OR6C68 | c.44T>G p.L15R | Missense Mutation (SNP) | VAF 72/141 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV65563559; called by muse, mutect2, varscan2
- OR8U1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 78/208 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs374110407; called by muse, mutect2, varscan2
- OSMR | c.40A>G p.T14A | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs551133663, COSV57087674; called by muse, mutect2, varscan2
- OVGP1 | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV63858457; called by muse, mutect2, varscan2
- P2RY14 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 48/102 reads (47%) | catalogued as COSV56385972; called by muse, mutect2, varscan2
- PAK6 | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs145812191; called by muse, mutect2, varscan2
- PAPPA2 | c.4126G>A p.E1376K | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs376402363, COSV62795460; called by muse, mutect2, varscan2
- PARP12 | c.797C>T p.T266I | Missense Mutation (SNP) | VAF 75/132 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as COSV54935635; called by muse, mutect2, varscan2
- PARP8 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV55862781; called by muse, mutect2, varscan2
- PCDH17 | c.2459C>T p.S820F | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV64976196; called by muse, mutect2, varscan2
- PCDHA11 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 86/208 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV56480685; called by muse, mutect2, varscan2
- PCDHA12 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.364); catalogued as rs1554168093, COSV56475083; called by muse, mutect2, varscan2
- PCDHA13 | c.2371G>A p.E791K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs781835096, COSV56522261; called by muse, mutect2, varscan2
- PCDHA3 | c.2191G>A p.D731N | Missense Mutation (SNP) | VAF 102/185 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV63540593; called by muse, mutect2, varscan2
- PCDHB12 | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV53398545; called by muse, mutect2, varscan2
- PCDHB12 | c.2360C>T p.P787L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs556781909, COSV53393598; called by muse, mutect2, varscan2
- PCDHB2 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.034); catalogued as COSV52031000; called by muse, mutect2, varscan2
- PCDHB3 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 121/277 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as rs1563837333, COSV50564880; called by muse, mutect2, varscan2
- PCLO | c.13397G>A p.R4466K | Missense Mutation (SNP) | VAF 109/162 reads (67%) | SIFT tolerated (0.35); PolyPhen benign (0.047); catalogued as COSV61647902; called by muse, mutect2, varscan2
- PCNT | c.1868G>A p.R623K | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs921988273, COSV64030327; called by muse, mutect2, varscan2
- PDE1C | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58519638; called by muse, mutect2, varscan2
- PDE1C | c.102-1G>A p.X34_splice | Splice Site (SNP) | VAF 32/55 reads (58%) | catalogued as COSV58519650; called by muse, mutect2, varscan2
- PDE3A | c.2803G>A p.E935K | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62976929; called by muse, mutect2, varscan2
- PDE4A | c.1910C>T p.S637F (on ENST00000380702 / NM_001111307.2; = p.S398F on NM_006202.3) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV53351407; called by muse, mutect2, varscan2
- PDGFRB | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs754790326, COSV55801719, COSV55804444; called by muse, mutect2, varscan2
- PEMT | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 67/80 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55130192, COSV55132050; called by muse, mutect2, varscan2
- PFKFB4 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 56/109 reads (51%) | PolyPhen benign (0.034); catalogued as rs555739425, COSV51681718; called by muse, mutect2, varscan2
- PHACTR3 | c.551del p.P184Lfs*25 | Frame Shift Del (DEL) | VAF 25/66 reads (38%) | catalogued as COSV63036146; called by mutect2, pindel, varscan2
- PHIP | c.3730C>T p.P1244S | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.912); catalogued as COSV99244345; called by muse, mutect2, varscan2
- PI4KA | c.6065G>A p.R2022Q | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.091); catalogued as rs778038442, COSV55415782; called by muse, mutect2, varscan2
- PI4KB | c.2380G>A p.D794N (on ENST00000368873 / NM_001369623.1; = p.D806N on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/108 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV55019364; called by muse, mutect2, varscan2
- PID1 | c.730G>A p.E244K (on ENST00000354069 / NM_001330156.1; = p.E242K on NM_017933.5) | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV62478415; called by muse, mutect2, varscan2
- PIDD1 | c.2539C>T p.P847S | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV57194062; called by muse, mutect2, varscan2
- PIGO | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99956752; called by muse, mutect2, varscan2
- PIK3R4 | c.3761C>T p.P1254L | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62030109; called by muse, mutect2, varscan2
- PITX2 | c.346G>A p.E116K (on ENST00000354925 / NM_001204397.1; = p.E123K on NM_000325.6) | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335923324, COSV60740620; called by muse, mutect2, varscan2
- PKHD1L1 | c.9539C>T p.S3180F | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV65747138; called by muse, mutect2, varscan2
- PLCE1 | c.689A>T p.Y230F | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.101); catalogued as rs376748611, COSV53359390; called by muse, mutect2, varscan2
- PLCE1 | c.4969G>A p.E1657K | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.955); catalogued as COSV53338673; called by muse, mutect2, varscan2
- PLEK2 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 107/257 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV53605957; called by muse, mutect2, varscan2
- PLXNA4 | c.4588G>A p.E1530K | Missense Mutation (SNP) | VAF 367/583 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV58141285; called by muse, mutect2, varscan2
- PNPLA6 | c.1829C>T p.S610F (on ENST00000414982 / NM_001166111.2; = p.S562F on NM_006702.5) | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as COSV55380986; called by muse, mutect2, varscan2
- POLE2 | c.629A>T p.K210I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.472); catalogued as COSV53560870; called by muse, mutect2
- POMT1 | c.1339-1G>A p.X447_splice | Splice Site (SNP) | VAF 133/446 reads (30%) | catalogued as COSV100586195, COSV61226709; called by muse, mutect2, varscan2
- PPFIA2 | c.3613G>A p.E1205K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.124); catalogued as COSV61041182; called by muse, mutect2, varscan2
- PPP1R12C | c.1513C>G p.P505A | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV54738539; called by muse, mutect2, varscan2
- PPP1R26 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 194/282 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1442796277, COSV63354942; called by muse, mutect2, varscan2
- PREX2 | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV55783205, COSV55802018; called by muse, mutect2, varscan2
- PREX2 | c.2786A>G p.H929R | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.109); catalogued as COSV55783225; called by muse, varscan2
- PROX1 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 103/153 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54778175; called by muse, mutect2, varscan2
- PRPF6 | c.2788C>T p.L930F | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53873898; called by muse, mutect2, varscan2
- PRRC2A | c.4321C>G p.R1441G | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65687834; called by muse, mutect2, varscan2
- PRRG3 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 41/42 reads (98%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as COSV64850928; called by muse, mutect2, varscan2
- PRUNE2 | c.2938G>A p.G980R | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as COSV65043765; called by muse, mutect2, varscan2
- PRUNE2 | c.2753C>T p.S918F | Missense Mutation (SNP) | VAF 205/294 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV65043769; called by muse, mutect2, varscan2
- PRUNE2 | c.1396C>T p.L466F | Missense Mutation (SNP) | VAF 54/80 reads (68%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758824978, COSV65043772; called by muse, mutect2, varscan2
- PSG4 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 95/201 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54937616; called by muse, mutect2, varscan2
- PSG7 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 101/196 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs1201678064, COSV68445773; called by muse, mutect2, varscan2
- PTCHD3 | c.2170G>A p.D724N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV71257114; called by muse, mutect2, varscan2
- PTPRA | c.2389G>A p.D797N | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.095); catalogued as COSV53784345; called by muse, mutect2, varscan2
- PTPRB | c.5194C>T p.R1732* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as rs724159879, COSV54246215; called by muse, mutect2, varscan2
- PTPRC | c.3645C>T p.F1215= | Splice Region (SNP) | VAF 41/145 reads (28%) | catalogued as rs1558042118, COSV61407374; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRN2 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 69/115 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs772824315, COSV101235017, COSV67048198; called by muse, mutect2, varscan2
- PTPRT | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368237025, COSV100626435; called by muse, mutect2, varscan2
- PWWP3B | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV61800686; called by muse, mutect2, varscan2
- PXDNL | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs1165654580, COSV62492637; called by muse, mutect2, varscan2
- RAB3IP | c.1004C>T p.P335L (on ENST00000550536 / NM_175623.4; = p.P319L on NM_022456.5) | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.142); catalogued as COSV56084737, COSV99923297; called by muse, mutect2, varscan2
- RANBP2 | c.7264C>T p.R2422C | Missense Mutation (SNP) | VAF 156/664 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs755911705, COSV51697236; called by muse, varscan2
- RAP1A | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.995); catalogued as COSV62728279; called by muse, mutect2, varscan2
- RB1CC1 | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 27/54 reads (50%) | catalogued as rs1292791891, COSV50256466; called by muse, mutect2, varscan2
- RBL2 | c.2434C>T p.P812S | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV50881631; called by muse, mutect2, varscan2
- RBM24 | c.434C>T p.S145F (on ENST00000379052 / NM_001143942.2; = p.S100F on NM_153020.2) | Missense Mutation (SNP) | VAF 179/316 reads (57%) | SIFT tolerated (0.7); PolyPhen benign (0.06); catalogued as COSV59004245; called by muse, mutect2, varscan2
- RBM47 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 83/168 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV55938073; called by muse, mutect2, varscan2
- RBM5 | c.1675A>G p.K559E | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV61738230; called by muse, mutect2, varscan2
- RBMS3 | c.1261G>A p.D421N (on ENST00000383767 / NM_001003793.3; = p.D405N on NM_014483.3) | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as rs779820044, COSV99822188; called by muse, mutect2, varscan2
- RBMXL1 | c.673T>C p.Y225H | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.132); catalogued as COSV53103209; called by muse, mutect2, varscan2
- RBP3 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as rs782333697; called by muse, mutect2, varscan2
- RC3H2 | c.2392C>T p.P798S | Missense Mutation (SNP) | VAF 86/153 reads (56%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as COSV61801319; called by muse, mutect2, varscan2
- RFX6 | c.2498C>T p.P833L | Missense Mutation (SNP) | VAF 86/94 reads (91%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); catalogued as rs866689448, COSV60586918; called by muse, mutect2, varscan2
- RGL4 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV51944644; called by muse, mutect2, varscan2
- RGL4 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV51944651; called by muse, mutect2, varscan2
- RGS7 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV58555490; called by muse, mutect2, varscan2
- RHEBL1 | c.103T>C p.Y35H | Missense Mutation (SNP) | VAF 134/254 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56504619; called by muse, mutect2, varscan2
- RIMBP3 | c.4165G>A p.D1389N | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.311); catalogued as rs766577628; called by muse, mutect2, varscan2
- RIMS1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT tolerated (0.87); PolyPhen benign (0.012); catalogued as COSV53466971; called by muse, mutect2, varscan2
- RIPOR3 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV50394214; called by muse, mutect2, varscan2
- RNF150 | c.510G>A p.M170I | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs971145118, COSV60787311; called by muse, mutect2, varscan2
- RORB | c.998G>A p.G333E (on ENST00000396204 / NM_001365023.1; = p.G322E on NM_006914.4) | Missense Mutation (SNP) | VAF 109/315 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs267602267, COSV65333261, COSV65340965; called by muse, mutect2, varscan2
- RP1 | c.4058C>T p.T1353I | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as rs1264769577, COSV55120843; called by muse, mutect2, varscan2
- RP1 | c.5905G>A p.E1969K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV55120851; called by muse, mutect2, varscan2
- RPP25 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV59120203; called by muse, mutect2, varscan2
- RPRD1A | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.608); catalogued as COSV59821943; called by muse, mutect2, varscan2
- RPTN | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 229/787 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV60167498; called by muse, mutect2, varscan2
- RREB1 | c.2051C>T p.A684V | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58554657; called by muse, mutect2, varscan2
- RSPH14 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.87); PolyPhen benign (0.01); catalogued as COSV53269985; called by muse, mutect2, varscan2
- RSRP1 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.132); catalogued as rs750829736, COSV54562782; called by muse, mutect2, varscan2
- SALL1 | c.1421A>G p.E474G | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99174700; called by muse, mutect2, varscan2
- SALL3 | c.2513C>T p.S838F | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV73306217; called by muse, mutect2, varscan2
- SAMD3 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 27/28 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60776508; called by muse, mutect2, varscan2
- SCGN | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760647578, COSV58546220; called by muse, mutect2, varscan2
- SCN10A | c.2710G>A p.D904N | Missense Mutation (SNP) | VAF 133/298 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774493534, COSV71862091; called by muse, mutect2, varscan2
- SCN10A | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV71862092; called by muse, mutect2, varscan2
- SCN2A | c.2565C>T p.L855= | Splice Region (SNP) | VAF 15/33 reads (45%) | catalogued as COSV51847591; called by muse, mutect2, varscan2
- SCN5A | c.2608G>A p.D870N | Missense Mutation (SNP) | VAF 115/244 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV61131088; called by muse, mutect2, varscan2
- SCN8A | c.4490C>T p.S1497L | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV61985941; called by muse, mutect2, varscan2
- SCN9A | c.4146G>A p.W1382* (on ENST00000303354; = p.W1371* on NM_002977.3) | Nonsense Mutation (SNP) | VAF 96/328 reads (29%) | catalogued as rs1553479096, COSV57615675; called by muse, mutect2, varscan2
- SCUBE3 | c.2476G>A p.A826T | Missense Mutation (SNP) | VAF 81/243 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1248624106, COSV51458427, COSV51459873; called by muse, mutect2, varscan2
- SEC14L3 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.09); catalogued as COSV53180476; called by muse, mutect2, varscan2
- SEC23B | c.1994C>T p.T665I | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV52721843, COSV52723883; called by muse, mutect2, varscan2
- SELE | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 91/138 reads (66%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.998); catalogued as COSV60976679; called by muse, mutect2, varscan2
- SEMA4G | c.1802T>C p.M601T (on ENST00000370250; = p.M606T on NM_017893.3) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV52969830; called by muse, mutect2, varscan2
- SEMA5B | c.2938G>A p.D980N | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV52102332; called by muse, mutect2, varscan2
- SEMA6B | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as rs759325386, COSV56704892; called by muse, mutect2, varscan2
- SEMG1 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.762); catalogued as COSV99725317; called by muse, mutect2, varscan2
- SETBP1 | c.1589G>A p.R530Q | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.356); catalogued as rs371223842; called by muse, varscan2
- SETBP1 | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 115/256 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56328575; called by muse, varscan2
- SEZ6L | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs752901613, COSV50657778; called by muse, mutect2, varscan2
- SFTPB | c.267+2T>C p.X89_splice | Splice Site (SNP) | VAF 30/59 reads (51%) | catalogued as COSV60893711; called by muse, mutect2, varscan2
- SHANK1 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); catalogued as rs1485513413, COSV53255645; called by muse, mutect2, varscan2
- SHCBP1L | c.1905G>A p.M635I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.061); catalogued as COSV62354242, COSV62355876; called by muse, mutect2, varscan2
- SHROOM1 | c.1418G>A p.G473E | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV60581912; called by muse, mutect2, varscan2
- SI | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52287827; called by muse, mutect2, varscan2
- SIGLEC8 | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 67/116 reads (58%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.529); catalogued as COSV58474597; called by muse, mutect2, varscan2
- SIPA1L2 | c.3215C>T p.P1072L | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as rs559117373, COSV53394127; called by muse, mutect2, varscan2
- SLAMF6 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 65/100 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1476698110, COSV63587605; called by muse, mutect2, varscan2
- SLC16A14 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.698); catalogued as COSV54616999; called by muse, mutect2, varscan2
- SLC17A6 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs138159912, COSV54138373; called by muse, mutect2, varscan2
- SLC22A10 | c.88T>A p.L30I | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60422175; called by muse, mutect2, varscan2
- SLC25A31 | c.269T>G p.V90G | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV55420102; called by muse, mutect2, varscan2
- SLC26A2 | c.892C>T p.H298Y | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); catalogued as rs1025069199, COSV53825806; called by muse, mutect2, varscan2
- SLC26A9 | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as COSV61604119; called by muse, mutect2, varscan2
- SLC27A2 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV51060465; called by muse, mutect2, varscan2
- SLC27A6 | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV52484935; called by muse, mutect2, varscan2
- SLC37A2 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 103/110 reads (94%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV53523375; called by muse, mutect2, varscan2
- SLC38A10 | c.3097G>A p.D1033N | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV66102461; called by muse, mutect2, varscan2
- SLC39A12 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.346); catalogued as rs782099546, COSV66200361; called by muse, mutect2, varscan2
- SLC5A8 | c.1619G>A p.S540N | Missense Mutation (SNP) | VAF 118/288 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73310893; called by muse, mutect2, varscan2
- SLC7A13 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs748074011, COSV52533423; called by muse, mutect2, varscan2
- SLC8A3 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 141/308 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1361493951, COSV63523371; called by muse, mutect2, varscan2
- SLC8A3 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV63523098; called by muse, mutect2, varscan2
- SLC8B1 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV52529192; called by muse, mutect2
- SLC9A9 | c.534-1G>C p.X178_splice | Splice Site (SNP) | VAF 33/67 reads (49%) | catalogued as rs748024076, COSV57234876, COSV57237040; called by muse, mutect2, varscan2
- SLCO6A1 | c.1487G>A p.G496E | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141543083; called by muse, mutect2, varscan2
- SLFN11 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as COSV57699542; called by muse, mutect2, varscan2
- SLIT3 | c.1735G>A p.G579R | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60619472; called by muse, mutect2, varscan2
- SLU7 | c.512A>T p.N171I | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV51788886; called by muse, mutect2, varscan2
- SMC1B | c.3031G>A p.D1011N | Missense Mutation (SNP) | VAF 78/155 reads (50%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV62531307; called by muse, mutect2, varscan2
- SNAPC4 | c.3989C>T p.S1330F | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as rs766759586, COSV53734913; called by muse, mutect2, varscan2
- SORCS2 | c.2527G>A p.E843K | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as rs375293868; called by muse, mutect2, varscan2
- SOX30 | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as COSV53938285; called by muse, mutect2, varscan2
- SOX7 | c.806C>G p.S269C | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV58731185; called by muse, mutect2, varscan2
- SPART | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV62086734; called by muse, mutect2, varscan2
- SPATA16 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 100/221 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV63531029; called by muse, mutect2, varscan2
- SPHKAP | c.2575G>A p.G859R | Missense Mutation (SNP) | VAF 140/231 reads (61%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs751100022, COSV100763870, COSV60885559; called by muse, mutect2, varscan2
- SPHKAP | c.1274G>A p.G425E | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV60885671; called by muse, mutect2, varscan2
- SPHKAP | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV60885685; called by muse, mutect2, varscan2
- SPINK5 | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.601); catalogued as rs374182762; called by muse, mutect2, varscan2
- SQOR | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 45/51 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV52942618; called by muse, mutect2, varscan2
- SRGAP3 | c.2363G>A p.G788D | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV64535964; called by muse, mutect2, varscan2
- SSBP2 | c.639G>A p.M213I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as COSV57800009; called by muse, mutect2, varscan2
- STAB2 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66342266; called by muse, mutect2, varscan2
- STAP1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.977); catalogued as COSV55328760; called by muse, mutect2, varscan2
- STK31 | c.2050C>T p.H684Y | Missense Mutation (SNP) | VAF 53/75 reads (71%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV63456062; called by muse, mutect2, varscan2
- STOML1 | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 42/79 reads (53%) | catalogued as rs1284805594, COSV57551301; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3008T>C p.L1003P | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV59133550; called by muse, mutect2, varscan2
- STRC | c.5153C>T p.P1718L | Missense Mutation (SNP) | VAF 44/52 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV55853005; called by muse, mutect2, varscan2
- STRN3 | c.1243G>A p.E415K (on ENST00000357479 / NM_001083893.2; = p.E331K on NM_014574.4) | Missense Mutation (SNP) | VAF 91/208 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV62580682; called by muse, mutect2, varscan2
- STXBP5L | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs561846083, COSV56522382; called by muse, mutect2, varscan2
- SULT1C2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV52265843; called by muse, mutect2, varscan2
- SYNRG | c.1568A>T p.D523V | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs1245832207; called by muse, mutect2, varscan2
- SYT6 | c.1523C>T p.P508L (on ENST00000610222 / NM_001366225.1; = p.P423L on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV65774875; called by muse, mutect2, varscan2
- SYT9 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs773842068, COSV59615893; called by muse, mutect2, varscan2
- TAS1R2 | c.1789C>T p.R597C | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs528333669, COSV64745579; called by muse, mutect2, varscan2
- TBC1D1 | c.1876C>T p.H626Y | Missense Mutation (SNP) | VAF 66/121 reads (55%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV54716250; called by muse, mutect2, varscan2
- TBC1D3F | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 110/238 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1412577595; called by mutect2, varscan2
- TENM2 | c.731G>A p.S244N (on ENST00000518659 / NM_001122679.2; = p.S53N on NM_001080428.3) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.01); catalogued as COSV69135314; called by muse, mutect2, varscan2
- TENM3 | c.4618G>A p.D1540N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as rs778883513, COSV101305501, COSV69313088; called by muse, mutect2, varscan2
- TENM3 | c.6599G>A p.R2200K | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV101305189; called by muse, mutect2, varscan2
- TENT5D | c.859C>T p.H287Y | Missense Mutation (SNP) | VAF 73/73 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100382755, COSV57637690; called by muse, mutect2, varscan2
- TEX15 | c.3712A>G p.S1238G (on ENST00000256246; = p.S1621G on NM_001350162.2) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs906966055, COSV56349356; called by muse, mutect2, varscan2
- TGFBI | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 172/376 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs771481298, COSV59350536; called by muse, mutect2, varscan2
- TGM7 | c.1787C>T p.S596F | Missense Mutation (SNP) | VAF 20/21 reads (95%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV71772932; called by muse, mutect2
- THEMIS | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV64069333; called by muse, mutect2, varscan2
- TIGD4 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV58550153; called by muse, mutect2, varscan2
- TLR2 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV52604824, COSV52605848, COSV52607158; called by muse, mutect2, varscan2
- TM7SF2 | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs771022046, COSV54205180; called by muse, mutect2, varscan2
- TMC2 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.119); catalogued as COSV62655373; called by muse, varscan2
- TMED5 | c.533G>A p.R178K | Missense Mutation (SNP) | VAF 115/268 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.4); catalogued as COSV64757219; called by muse, mutect2, varscan2
- TMEM119 | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs766690800, COSV101219446, COSV67188948; called by muse, mutect2, varscan2
- TMEM182 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV68425311; called by muse, mutect2, varscan2
- TMEM236 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 83/186 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs940782752; called by muse, mutect2, varscan2
- TMEM59L | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1568446647, COSV53241562; called by muse, mutect2, varscan2
- TMPO | c.1312C>T p.Q438* | Nonsense Mutation (SNP) | VAF 33/99 reads (33%) | catalogued as COSV58462593; called by muse, mutect2, varscan2
- TMPRSS11D | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.911); catalogued as rs748284731, COSV52224485; called by muse, mutect2, varscan2
- TMPRSS15 | c.2862G>A p.M954I | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV53043163; called by muse, mutect2, varscan2
- TNIP3 | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.21); PolyPhen benign (0.11); catalogued as COSV50247755, COSV99284179; called by muse, mutect2, varscan2
- TNNI2 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs376094620, COSV53290285; called by muse, varscan2
- TNR | c.3472G>A p.G1158R | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.083); catalogued as rs1341192221, COSV54885065, COSV54897992; called by muse, mutect2, varscan2
- TOX3 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 96/214 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54863429, COSV54863946; called by muse, mutect2, varscan2
- TPTE2 | c.938A>T p.E313V (on ENST00000400230 / NM_199254.2; = p.E236V on NM_130785.3) | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV55024480; called by muse, mutect2, varscan2
- TRGV5 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.217); catalogued as rs1198283354; called by muse, mutect2, varscan2
- TRHDE | c.2287C>T p.P763S | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as COSV53831788; called by muse, mutect2, varscan2
- TRIM48 | c.51G>A p.M17I | Missense Mutation (SNP) | VAF 125/288 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs754486791, COSV70161112; called by muse, mutect2, varscan2
- TRPC4 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs781609904, COSV59000384; called by muse, mutect2, varscan2
- TRPC4 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59004943; called by muse, mutect2, varscan2
- TRPM2 | c.2266G>A p.V756M | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV55972558; called by muse, mutect2, varscan2
- TTC17 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 107/229 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1250733801, COSV50012002; called by muse, mutect2, varscan2
- TTLL4 | c.3452C>T p.S1151F | Missense Mutation (SNP) | VAF 117/199 reads (59%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV51437594; called by muse, mutect2, varscan2
- TTN | c.63719G>A p.R21240Q (on ENST00000591111; = p.R13816Q on NM_003319.4) | Missense Mutation (SNP) | VAF 40/147 reads (27%) | PolyPhen benign (0.007); catalogued as rs772700244, COSV60158740; called by muse, mutect2, varscan2
- TTN | c.34132C>T p.P11378S (on ENST00000591111; = p.P10451S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/51 reads (57%) | PolyPhen benign (0.007); catalogued as COSV60176725; called by muse, mutect2, varscan2
- TTN | c.15760C>T p.P5254S (on ENST00000591111; = p.P4327S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/201 reads (25%) | PolyPhen probably damaging (0.998); catalogued as rs566415754, COSV100623924, COSV60176740; called by muse, mutect2, varscan2
- TTN | c.6473G>A p.G2158E (on ENST00000591111; = p.G2112E on NM_003319.4) | Missense Mutation (SNP) | VAF 79/135 reads (59%) | PolyPhen probably damaging (1); catalogued as COSV59964803, COSV60045227; called by muse, mutect2, varscan2
- TUBA3D | c.1306G>A p.G436S | Missense Mutation (SNP) | VAF 107/270 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.89); catalogued as COSV58311715; called by muse, mutect2, varscan2
- UBE2E3 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV66585483; called by muse, mutect2, varscan2
- UBQLN3 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.618); catalogued as COSV61164748; called by muse, mutect2, varscan2
- UBR5 | c.3182C>T p.P1061L | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as COSV55299540; called by muse, mutect2, varscan2
- UBR5 | c.3181C>T p.P1061S | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.968); catalogued as COSV55299551; called by muse, mutect2, varscan2
- UGT2A2 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.218); catalogued as COSV54143908; called by muse, mutect2, varscan2
- UNC5D | c.573G>A p.V191= | Splice Region (SNP) | VAF 17/40 reads (43%) | catalogued as COSV54810458; called by muse, mutect2, varscan2
- UNC5D | c.1568C>T p.P523L | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV54810473; called by muse, mutect2, varscan2
- UNC79 | c.530C>T p.T177M | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as rs781373307, COSV56388144; called by muse, mutect2, varscan2
- USP20 | c.1562G>T p.R521L | Missense Mutation (SNP) | VAF 57/112 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV59615993; called by muse, mutect2, varscan2
- USP28 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1483489513, COSV50170799; called by muse, mutect2, varscan2
- USP29 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV54142884, COSV54147687; called by muse, mutect2, varscan2
- USP7 | c.1424G>C p.G475A | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); catalogued as COSV61215846; called by muse, mutect2, varscan2
- VAC14 | c.2275C>T p.Q759* | Nonsense Mutation (SNP) | VAF 39/80 reads (49%) | catalogued as COSV55755315; called by muse, mutect2, varscan2
- VRTN | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV56442136; called by muse, mutect2, varscan2
- VWF | c.8096A>C p.H2699P | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV99779361; called by muse, mutect2, varscan2
- WNT3A | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 80/135 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs761411292, COSV52732186; called by muse, mutect2, varscan2
- XAGE3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 61/66 reads (92%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV60569703; called by muse, mutect2, varscan2
- XDH | c.2686C>T p.R896W | Missense Mutation (SNP) | VAF 87/270 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs765576781, COSV65147792; called by muse, mutect2, varscan2
- XPNPEP2 | c.467T>A p.F156Y | Missense Mutation (SNP) | VAF 177/185 reads (96%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); catalogued as COSV64368050; called by muse, mutect2, varscan2
- XPOT | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 68/130 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs765498017, COSV60346572; called by muse, mutect2, varscan2
- XRRA1 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 96/221 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58498998; called by muse, mutect2, varscan2
- YME1L1 | c.1145G>A p.G382E (on ENST00000326799 / NM_139312.3; = p.G325E on NM_014263.4) | Missense Mutation (SNP) | VAF 66/134 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58760353; called by muse, mutect2, varscan2
- ZC3H7A | c.136C>T p.L46F | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63270350; called by muse, mutect2, varscan2
- ZCCHC14 | c.2450C>T p.P817L (on ENST00000268616; = p.P954L on NM_015144.3) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs745771333, COSV51887936; called by muse, mutect2, varscan2
- ZEB1 | c.959C>G p.P320R | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV58048808; called by muse, mutect2, varscan2
- ZGRF1 | c.2492C>T p.S831L | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs762410665, COSV52200100; called by muse, mutect2, varscan2
- ZNF138 | c.680T>G p.V227G (on ENST00000307355 / NM_001367572.1; = p.V201G on NM_006524.4) | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV56466156; called by muse, mutect2, varscan2
- ZNF148 | c.462C>T p.I154= | Splice Region (SNP) | VAF 21/64 reads (33%) | catalogued as rs765045591, COSV62304062; called by muse, varscan2
- ZNF19 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV55508195; called by muse, mutect2, varscan2
- ZNF212 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 71/300 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60025515; called by muse, mutect2, varscan2
- ZNF214 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV53482745; called by muse, mutect2, varscan2
- ZNF331 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 131/263 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV99467474; called by muse, mutect2, varscan2
- ZNF385D | c.248A>G p.N83S | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.992); catalogued as COSV55763946; called by muse, mutect2, varscan2
- ZNF407 | c.1226G>A p.S409N | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV55259777; called by muse, mutect2, varscan2
- ZNF423 | c.113G>A p.G38E (on ENST00000563137 / NM_001379286.1; = p.G30E on NM_015069.4) | Missense Mutation (SNP) | VAF 100/334 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.062); catalogued as COSV52196392; called by muse, mutect2, varscan2
- ZNF462 | c.1349A>G p.H450R | Missense Mutation (SNP) | VAF 142/224 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52944752; called by muse, mutect2, varscan2
- ZNF471 | c.1861C>T p.H621Y | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57292278; called by muse, mutect2, varscan2
- ZNF501 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.629); catalogued as rs1393349378, COSV68516439; called by muse, mutect2, varscan2
- ZNF524 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV55608387; called by muse, mutect2, varscan2
- ZNF560 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV56869427; called by muse, mutect2, varscan2
- ZNF804A | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1438894921, COSV56457698; called by muse, mutect2, varscan2
- ZNF804A | c.2342C>T p.S781L | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56454928; called by muse, mutect2, varscan2
- ZNF804A | c.2519C>A p.S840Y | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV56457717; called by muse, mutect2, varscan2
- ZNF808 | c.2185C>T p.H729Y | Missense Mutation (SNP) | VAF 114/262 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV63120591; called by muse, mutect2, varscan2
- ZNF816 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV54411449; called by muse, mutect2, varscan2
- ZP3 | c.709C>T p.H237Y (on ENST00000394857 / NM_001110354.2; = p.H186Y on NM_007155.6) | Missense Mutation (SNP) | VAF 75/240 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.289); catalogued as COSV60634147; called by muse, mutect2, varscan2
- ZSWIM2 | c.1259A>T p.K420I | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54577019; called by muse, mutect2, varscan2
- AMY2A | c.1221G>A p.R407= | Splice Region (SNP) | VAF 13/54 reads (24%) | called by mutect2, varscan2
- CDC42EP1 | c.228_245delinsG p.S77Gfs*92 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by pindel, varscan2*
- CFHR3 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.021); called by mutect2, varscan2
- CMC1 | c.271del p.T91Lfs*22 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | called by pindel, varscan2
- CSAG3 | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FOXD4L4 | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.026); called by mutect2, varscan2
- GPR179 | c.5191G>A p.D1731N (on ENST00000621958; = p.D1730N on NM_001004334.4) | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IGKV3-15 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 61/360 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- IGLV3-32 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8G2P | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 57/64 reads (89%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TAS2R50 | c.406_409del p.T136* | Frame Shift Del (DEL) | VAF 124/272 reads (46%) | called by mutect2, pindel, varscan2
- TPTE | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- TRAV12-3 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ABCA10 | c.2967C>T p.F989= | Silent (SNP) | VAF 53/193 reads (27%) | catalogued as COSV52225820; called by muse, mutect2, varscan2
- ABCA12 | c.564T>C p.Y188= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs765867091, COSV55966335; called by muse, mutect2, varscan2
- ABCA8 | c.3048G>A p.R1016= | Silent (SNP) | VAF 181/325 reads (56%) | catalogued as COSV52206160; called by muse, mutect2, varscan2
- ABCG4 | c.1509C>T p.F503= | Silent (SNP) | VAF 49/55 reads (89%) | catalogued as rs1307437686, COSV56644521; called by muse, mutect2, varscan2
- ABHD11 | c.849C>T p.F283= | Silent (SNP) | VAF 61/108 reads (56%) | catalogued as rs1554621843, COSV56106065; called by muse, mutect2, varscan2
- ACOXL | c.813C>T p.T271= | Silent (SNP) | VAF 59/147 reads (40%) | catalogued as rs1558711078, COSV67737145; called by muse, mutect2, varscan2
- ADAM29 | c.1521G>A p.R507= | Silent (SNP) | VAF 62/146 reads (42%) | catalogued as rs267600092, COSV63661987, COSV63664066; called by muse, mutect2, varscan2
- ADAMTS18 | c.3657G>A p.R1219= | Silent (SNP) | VAF 49/128 reads (38%) | catalogued as COSV51417626; called by muse, mutect2, varscan2
- ADAP1 | c.825C>T p.F275= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as COSV56215406; called by muse, mutect2, varscan2
- ADGRD1 | c.720C>T p.I240= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as rs562234701, COSV55450259; called by muse, mutect2, varscan2
- ADGRL2 | c.639G>A p.V213= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV54675917; called by muse, mutect2, varscan2
- ADIPOR1 | c.924G>A p.V308= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as COSV61850946, COSV61851939; called by muse, mutect2, varscan2
- AFP | c.1131C>T p.Y377= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV99890076; called by muse, mutect2, varscan2
- ALK | c.879C>T p.I293= | Silent (SNP) | VAF 166/246 reads (67%) | catalogued as COSV66576873; called by muse, mutect2, varscan2
- ALKAL1 | c.240C>T p.F80= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV62130747; called by muse, mutect2, varscan2
- ALPI | c.747G>A p.G249= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV55015245; called by muse, mutect2, varscan2
- ANGPTL2 | c.1413C>T p.F471= | Silent (SNP) | VAF 90/344 reads (26%) | catalogued as COSV52226044; called by muse, mutect2, varscan2
- ANKRD26 | c.1930C>T p.L644= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV65776563; called by muse, mutect2, varscan2
- ANKRD30A | c.3726G>A p.T1242= (on ENST00000611781; = p.T1186= on NM_052997.2) | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs566578534, COSV64603948; called by muse, mutect2, varscan2
- ANO10 | c.1320C>T p.S440= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as COSV52733298; called by muse, mutect2, varscan2
- ANO2 | c.963C>T p.D321= (on ENST00000356134 / NM_001278597.3; = p.D325= on NM_001278596.3) | Silent (SNP) | VAF 36/68 reads (53%) | catalogued as rs571512821, COSV59031666; called by muse, mutect2, varscan2
- ANXA9 | c.477C>T p.F159= | Silent (SNP) | VAF 42/122 reads (34%) | catalogued as COSV64485207; called by muse, mutect2, varscan2
- ARHGAP21 | c.3681C>T p.F1227= | Silent (SNP) | VAF 37/67 reads (55%) | catalogued as COSV57608454; called by muse, mutect2, varscan2
391 further variants in this file (0 protein-altering or splice-affecting, 357 silent, 34 other) are not listed here.
